Somatic mutation profile of tumor specimen 0DVU3I from CCDI case PBCNEA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Descended testis; Age at diagnosis: 3.6 years (1,310 days).
Specimen 0DVU3I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5709086f-25cb-4ed3-b955-63fa3d5566c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVU3V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbb6aff8-5d9e-4879-8dce-1bed05c50689

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Intron 2, 3'UTR 2, Splice Region 1, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 266/357 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs763170320; called by muse, mutect2, varscan2
- KCNAB2 | c.281+4C>T | Splice Region (SNP) | VAF 61/186 reads (33%) | catalogued as rs1295028906; called by muse, mutect2, varscan2
- PER3 | c.1853C>T p.T618M | Missense Mutation (SNP) | VAF 150/570 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs759601919; called by muse, varscan2
- SH3GL2 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 128/601 reads (21%) | catalogued as rs1471921718; called by muse, mutect2, varscan2
- USP7 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 163/742 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV61217515; called by muse, mutect2, varscan2
- DNAH5 | c.2769C>A p.D923E | Missense Mutation (SNP) | VAF 70/784 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- ERP44 | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 312/1009 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIAA0586 | c.2744A>G p.E915G (on ENST00000619416 / NM_001244190.2; = p.E854G on NM_014749.5) | Missense Mutation (SNP) | VAF 184/707 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- NBEAL2 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 141/433 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLG | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 164/667 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- PRDM2 | c.4219G>A p.V1407I | Missense Mutation (SNP) | VAF 285/1012 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- RNF122 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 296/554 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); called by muse, varscan2
- THOC2 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 233/462 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ACAN | c.189C>A p.A63= | Silent (SNP) | VAF 183/616 reads (30%) | called by muse, mutect2, varscan2
- CCDC87 | c.2475G>T p.R825= | Silent (SNP) | VAF 180/582 reads (31%) | catalogued as rs551450850, COSV100040068; called by muse, mutect2, varscan2
- CRTC1 | c.1635G>A p.P545= | Silent (SNP) | VAF 91/333 reads (27%) | catalogued as rs752843264; called by muse, mutect2, varscan2
- DRG2 | c.849T>C p.L283= | Silent (SNP) | VAF 125/496 reads (25%) | catalogued as rs777727119; called by muse, mutect2, varscan2
- SLC36A2 | c.1272G>A p.P424= | Silent (SNP) | VAF 123/454 reads (27%) | catalogued as rs375688437; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 14/286 reads (5%) | called by muse, mutect2
- HPGDS | c.226+88C>T | Intron (SNP) | VAF 8/197 reads (4%) | called by muse, mutect2
- PRDM12 | c.*27G>A | 3'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, varscan2
- SMOX | c.*12G>C | 3'UTR (SNP) | VAF 42/141 reads (30%) | called by muse, mutect2, varscan2
